Somatic mutation profile of tumor specimen C3L-00079-01 (aliquot CPT0001260005) from CPTAC case C3L-00079, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 49.3 years (18,021 days).
Specimen C3L-00079-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4ffc028-282f-4f58-b2d6-4aaaee0364e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00079-31 (Blood Derived Normal), aliquot CPT0000070163; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b805a7a-4130-40c7-ba61-1d2a1eb303ef

The open-access MAF lists 136 somatic variants for this specimen: 98 protein-altering or splice-affecting, 22 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 22, Frame Shift Del 7, Intron 6, RNA 4, Nonsense Mutation 4, 3'Flank 3, 3'UTR 3, Splice Site 3, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.395G>A p.G132D | Missense Mutation (SNP) | VAF 146/463 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs121909241, CM045431, CM063078, CM074468, COSV64288421, COSV64288528, COSV64293854; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.4970G>A p.R1657H (on ENST00000303395 / NM_001202435.3; = p.R1646H on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/233 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121917994, CM072002; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- BCL2 | c.622C>G p.P208A | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.437); catalogued as COSV100384954; called by muse, mutect2, varscan2
- BTBD1 | c.1009C>G p.Q337E | Missense Mutation (SNP) | VAF 64/417 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as rs770696742; called by muse, mutect2, varscan2
- BTBD19 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1306315037; called by muse, mutect2
- CD68 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 48/313 reads (15%) | SIFT tolerated (0.79); PolyPhen benign (0.089); catalogued as rs1163905117; called by muse, mutect2, varscan2
- CLPB | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as rs772243585; called by muse, mutect2
- COL9A1 | c.570T>A p.S190R | Missense Mutation (SNP) | VAF 65/221 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV61833336; called by muse, mutect2, varscan2
- CRACR2A | c.1736-1G>C p.X579_splice | Splice Site (SNP) | VAF 14/180 reads (8%) | catalogued as COSV61542032; called by muse, mutect2
- CSMD2 | c.7649G>A p.G2550E | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.631); catalogued as COSV53907800; called by muse, mutect2, varscan2
- DCC | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 38/494 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200830938; called by muse, mutect2
- DCTN6 | c.302T>C p.M101T | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs752311748; called by muse, mutect2, varscan2
- DCTN6 | c.303G>T p.M101I | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99644970; called by muse, mutect2, varscan2
- ELOVL4 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 27/456 reads (6%) | SIFT tolerated (0.64); PolyPhen benign (0.011); catalogued as rs946012914; called by muse, mutect2
- FILIP1 | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV52736023; called by muse, mutect2, varscan2
- FRY | c.2306C>T p.A769V | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as rs755738376; called by muse, mutect2
- GABRR2 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149245573, COSV68764867; called by muse, mutect2
- GGT7 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 36/307 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.411); catalogued as rs371027305; called by muse, mutect2, varscan2
- GPR42 | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 46/281 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as rs766726297; called by muse, mutect2, varscan2
- KIAA1755 | c.2269-8G>T | Splice Region (SNP) | VAF 18/198 reads (9%) | catalogued as rs762034055; called by muse, mutect2
- KRT20 | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 15/250 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs545785377, COSV51424493; called by muse, mutect2
- LMTK2 | c.3739C>G p.L1247V | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.079); catalogued as COSV52004068; called by muse, mutect2, varscan2
- MON1A | c.1571G>A p.R524Q | Missense Mutation (SNP) | VAF 75/193 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0.011); catalogued as rs780927557; called by muse, mutect2, varscan2
- NPC1L1 | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 44/512 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.116); catalogued as rs757842457; called by muse, mutect2
- PLG | c.2408T>C p.I803T | Missense Mutation (SNP) | VAF 21/330 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1232305777; called by muse, mutect2
- PPP1R10 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as rs776493915; called by muse, mutect2, varscan2
- RAF1 | c.1337T>C p.I446T | Missense Mutation (SNP) | VAF 101/263 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1391168607; called by muse, mutect2, varscan2
- RALGAPB | c.1469C>T p.S490F | Missense Mutation (SNP) | VAF 50/357 reads (14%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.989); catalogued as COSV53443917; called by muse, mutect2, varscan2
- SCAF8 | c.3479G>C p.R1160T | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.321); catalogued as rs765106393, COSV65791997; called by muse, mutect2, varscan2
- SOHLH1 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372516323; called by muse, mutect2, varscan2
- SUSD4 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.357); catalogued as rs369486252; called by muse, mutect2, varscan2
- TMEM108 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.436); catalogued as rs779231884, COSV58868845; called by muse, mutect2, varscan2
- TRIM42 | c.700G>T p.G234W | Missense Mutation (SNP) | VAF 15/241 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV53883390; called by muse, mutect2
- TTBK1 | c.581G>T p.R194L | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52495919, COSV99445173; called by muse, mutect2
- VPS13D | c.4337G>A p.G1446E | Missense Mutation (SNP) | VAF 39/254 reads (15%) | SIFT tolerated (0.91); PolyPhen benign (0.06); catalogued as rs1396103679; called by muse, mutect2, varscan2
- WNT9B | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.922); catalogued as rs139617595; called by muse, mutect2
- ABCA4 | c.5966C>G p.T1989S | Missense Mutation (SNP) | VAF 68/424 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- ACSS2 | c.1987A>G p.M663V | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ARHGAP35 | c.1385A>G p.E462G | Missense Mutation (SNP) | VAF 67/220 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- ARMC2 | c.1255G>T p.A419S | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- B3GALT1 | c.708T>A p.C236* | Nonsense Mutation (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- BCAT1 | c.357A>C p.R119S | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- BVES | c.661G>T p.A221S | Missense Mutation (SNP) | VAF 24/396 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- C8orf76 | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.408); called by muse, mutect2
- CADPS2 | c.1016G>T p.R339L | Missense Mutation (SNP) | VAF 35/254 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- CHST4 | c.756C>A p.S252R | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYP2D6 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 146/486 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, varscan2
- CYP2D6 | c.324G>T p.Q108H | Missense Mutation (SNP) | VAF 152/403 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.186); called by muse, varscan2
- DOCK7 | c.3356T>A p.L1119Q (on ENST00000635253 / NM_001367561.1; = p.L1088Q on NM_033407.3) | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- DSCAM | c.3574C>G p.P1192A | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- DSG2 | c.2118A>T p.K706N | Missense Mutation (SNP) | VAF 23/448 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.343); called by muse, mutect2
- DUS2 | c.652C>G p.H218D | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2
- ELOA2 | c.614C>A p.P205H | Missense Mutation (SNP) | VAF 32/411 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.926); called by muse, mutect2
- FAM90A10P | c.1105T>C p.C369R | Missense Mutation (SNP) | VAF 139/265 reads (52%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- FASTKD3 | c.250G>C p.V84L | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FAT1 | c.3801_3807del p.R1267Sfs*7 | Frame Shift Del (DEL) | VAF 60/292 reads (21%) | called by mutect2, pindel, varscan2
- FMN1 | c.4168T>C p.S1390P (on ENST00000616417 / NM_001277313.2; = p.S1167P on NM_001103184.4) | Missense Mutation (SNP) | VAF 41/260 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- FTH1 | c.432del p.A145Pfs*9 | Frame Shift Del (DEL) | VAF 153/517 reads (30%) | called by mutect2, pindel, varscan2
- GMCL1 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- GOLGB1 | c.8068G>A p.D2690N | Missense Mutation (SNP) | VAF 7/196 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.079); called by muse, mutect2
- HCN1 | c.272A>G p.Y91C | Missense Mutation (SNP) | VAF 48/349 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- HEY2 | c.245A>T p.Q82L | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- IGKV1-9 | c.11G>C p.R4T | Missense Mutation (SNP) | VAF 41/345 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- KDM5C | c.415del p.Q139Sfs*95 | Frame Shift Del (DEL) | VAF 53/198 reads (27%) | called by mutect2, pindel, varscan2
- KIAA0319 | c.2975A>C p.K992T | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- LEMD2 | c.1157-1G>A p.X386_splice | Splice Site (SNP) | VAF 19/190 reads (10%) | called by muse, mutect2, varscan2
- MAP3K5 | c.888G>T p.L296F | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MCM9 | c.1492G>T p.D498Y | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MDN1 | c.3060G>C p.K1020N | Missense Mutation (SNP) | VAF 17/239 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.273); called by muse, mutect2
- MFSD2A | c.125C>G p.S42C | Missense Mutation (SNP) | VAF 13/224 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2
- N4BP2 | c.4350_4351del p.T1451Wfs*3 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | called by mutect2, pindel, varscan2
- PDE4B | c.495del p.I165Mfs*2 | Frame Shift Del (DEL) | VAF 51/235 reads (22%) | called by mutect2, pindel, varscan2
- PDSS2 | c.811A>T p.K271* | Nonsense Mutation (SNP) | VAF 82/321 reads (26%) | called by muse, mutect2, varscan2
- PHC1 | c.2410G>T p.G804W | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- PKD1L2 | c.1417T>G p.S473A | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- PKHD1L1 | c.7538T>C p.V2513A | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, varscan2
- PSG4 | c.656T>C p.I219T | Missense Mutation (SNP) | VAF 37/225 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- PTBP1 | c.1327T>A p.S443T (on ENST00000349038 / NM_031991.4; = p.S469T on NM_002819.5) | Missense Mutation (SNP) | VAF 148/492 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTPRK | c.4267G>T p.E1423* (on ENST00000368215 / NM_001291984.2; = p.E1424* on NM_002844.4) | Nonsense Mutation (SNP) | VAF 13/99 reads (13%) | called by muse, mutect2, varscan2
- PUF60 | c.454T>A p.F152I (on ENST00000526683 / NM_001362896.2; = p.F135I on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- RP1 | c.1039-1G>A p.X347_splice | Splice Site (SNP) | VAF 6/77 reads (8%) | called by muse, mutect2
- RPL5 | c.559del p.S187Afs*25 | Frame Shift Del (DEL) | VAF 42/343 reads (12%) | called by mutect2, pindel, varscan2
- SIX4 | c.1126G>T p.V376F | Missense Mutation (SNP) | VAF 66/190 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- SLC10A1 | c.552G>T p.M184I | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC16A10 | c.1235G>C p.G412A | Missense Mutation (SNP) | VAF 42/563 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SNX20 | c.895_897del p.P299del | In Frame Del (DEL) | VAF 19/74 reads (26%) | called by mutect2, pindel, varscan2
- SPTA1 | c.795C>G p.N265K | Missense Mutation (SNP) | VAF 22/450 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2
- STMN3 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 56/342 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- THEG | c.491T>C p.F164S | Missense Mutation (SNP) | VAF 42/237 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- TRIM31 | c.75A>T p.K25N | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.115); called by muse, mutect2
- TRPM8 | c.777T>G p.H259Q | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- USP34 | c.7821G>C p.L2607F | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- UTP14C | c.325G>T p.V109F | Missense Mutation (SNP) | VAF 51/700 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); called by muse, mutect2
- VHL | c.180_184del p.P61Afs*69 | Frame Shift Del (DEL) | VAF 177/309 reads (57%) | called by mutect2, pindel, varscan2
- YLPM1 | c.796G>T p.E266* | Nonsense Mutation (SNP) | VAF 41/159 reads (26%) | called by muse, mutect2, varscan2
- ZC3H7B | c.2784G>T p.Q928H | Missense Mutation (SNP) | VAF 40/438 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.067); called by muse, mutect2
- ZC3H7B | c.2786A>G p.K929R | Missense Mutation (SNP) | VAF 40/438 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.919); called by muse, mutect2
- ZNF324B | c.531G>C p.K177N | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- ANKFN1 | c.861C>T p.L287= | Silent (SNP) | VAF 7/145 reads (5%) | called by muse, mutect2
- ARHGAP32 | c.1455C>T p.V485= (on ENST00000310343 / NM_001378025.1; = p.V136= on NM_014715.4) | Silent (SNP) | VAF 39/288 reads (14%) | called by muse, mutect2, varscan2
- CACNA1C | c.1770C>A p.R590= | Silent (SNP) | VAF 17/125 reads (14%) | called by muse, mutect2, varscan2
- DDX60 | c.4092C>G p.L1364= | Silent (SNP) | VAF 22/346 reads (6%) | called by muse, mutect2
- DOCK5 | c.525T>C p.P175= | Silent (SNP) | VAF 44/234 reads (19%) | called by muse, mutect2
- FAT3 | c.2799C>T p.S933= | Silent (SNP) | VAF 42/252 reads (17%) | called by muse, mutect2, varscan2
- FKBP8 | c.189G>A p.A63= | Silent (SNP) | VAF 20/266 reads (8%) | catalogued as rs368959673; called by muse, mutect2
- FOXF1 | c.1107C>T p.V369= | Silent (SNP) | VAF 25/272 reads (9%) | catalogued as rs773537585; called by muse, mutect2
- FOXI1 | c.420C>T p.P140= | Silent (SNP) | VAF 38/614 reads (6%) | catalogued as rs772507619; called by muse, mutect2
- IGKV1-27 | c.150C>G p.G50= | Silent (SNP) | VAF 28/480 reads (6%) | called by muse, mutect2
- MEI1 | c.117G>A p.V39= | Silent (SNP) | VAF 14/216 reads (6%) | called by muse, mutect2
- MLIP | c.54G>A p.E18= | Silent (SNP) | VAF 23/280 reads (8%) | called by muse, mutect2
- MOCOS | c.303C>T p.I101= | Silent (SNP) | VAF 23/177 reads (13%) | catalogued as COSV54346997; called by muse, mutect2, varscan2
- NCAM1 | c.2052G>T p.V684= (on ENST00000316851 / NM_181351.5; = p.V674= on NM_000615.7) | Silent (SNP) | VAF 16/128 reads (13%) | catalogued as COSV57509868; called by muse, mutect2, varscan2
- PDCD6 | c.291C>T p.N97= | Silent (SNP) | VAF 26/317 reads (8%) | catalogued as rs149099614; called by muse, mutect2
- PRF1 | c.381C>T p.N127= | Silent (SNP) | VAF 81/267 reads (30%) | catalogued as rs531190813, COSV64615992; called by muse, mutect2, varscan2
- RDH5 | c.165C>G p.V55= | Silent (SNP) | VAF 14/226 reads (6%) | called by muse, mutect2
- RSPO2 | c.528T>A p.I176= | Silent (SNP) | VAF 58/257 reads (23%) | catalogued as rs200806324; called by muse, mutect2, varscan2
- SIDT2 | c.930G>A p.L310= | Silent (SNP) | VAF 32/193 reads (17%) | called by muse, mutect2, varscan2
- SOX5 | c.2088A>C p.S696= | Silent (SNP) | VAF 23/312 reads (7%) | called by muse, mutect2
- SRSF12 | c.591A>G p.S197= | Silent (SNP) | VAF 66/270 reads (24%) | called by muse, mutect2, varscan2
- UBAP1L | c.942G>A p.L314= | Silent (SNP) | VAF 71/205 reads (35%) | called by muse, mutect2, varscan2
- AC005702.1 | chr17:59976719 G>A | 3'Flank (SNP) | VAF 29/126 reads (23%) | called by muse, mutect2, varscan2
- AC023469.1 | n.324C>G | RNA (SNP) | VAF 12/184 reads (7%) | called by muse, mutect2
- ALMS1P1 | n.881G>C | RNA (SNP) | VAF 51/194 reads (26%) | called by muse, mutect2, varscan2
- AP2A2 | c.*571_*574del | 3'UTR (DEL) | VAF 15/142 reads (11%) | called by mutect2, pindel, varscan2
- COG6 | c.540+534C>T | Intron (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- CTSC | c.758-49G>A | Intron (SNP) | VAF 59/225 reads (26%) | called by muse, mutect2, varscan2
- CUL2 | c.-22-2763G>T | Intron (SNP) | VAF 18/240 reads (8%) | called by muse, mutect2
- FMO6P | n.977C>A | RNA (SNP) | VAF 49/232 reads (21%) | called by muse, mutect2, varscan2
- GPATCH2L | c.-11+809dup | Intron (INS) | VAF 18/104 reads (17%) | called by mutect2, pindel
- HIBADH | c.252+1762C>T | Intron (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
- IGHG1 | chr14:105737762 C>G | 3'Flank (SNP) | VAF 49/305 reads (16%) | catalogued as rs1309419713; called by muse, mutect2, varscan2
- LEKR1 | c.*562G>C | 3'UTR (SNP) | VAF 8/94 reads (9%) | catalogued as rs1355913937; called by muse, mutect2
- SEPTIN8 | c.1286+1834del | Intron (DEL) | VAF 12/130 reads (9%) | called by mutect2, pindel
- SNORD116-20 | n.92C>G | RNA (SNP) | VAF 100/447 reads (22%) | catalogued as rs1420961758; called by muse, mutect2, varscan2
- SYT14 | chr1:210163787 G>A | 3'Flank (SNP) | VAF 26/369 reads (7%) | catalogued as rs1170895436, COSV55055689; called by muse, mutect2
- VAPB | c.*1391G>T | 3'UTR (SNP) | VAF 101/296 reads (34%) | called by muse, mutect2, varscan2
